CPTAC case C3N-03061 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2afd7fdf-b52a-4945-8688-07ed694d630a

Demographics
Sex at birth: female; Race: asian; Year of birth: 1955; Vital status: Dead; Days to death: 139 days; Year of death: 2018; Country of birth: China.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Age at diagnosis: 62.9 years (22,974 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 139 days; Progression or recurrence: yes; Days to last follow up: 120 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 8; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 120 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 33 days; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 243 days; Disease response: Progressive Disease; Karnofsky performance status: 50; ECOG performance status: 3.

Other clinical attributes
- Weight: 43 kg; Height: 150 cm; BMI: 19.11.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03061-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 150 mg; Time between clamping and freezing: 18 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03061-21: Section location: Body; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-03061-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 170 mg; Time between clamping and freezing: 18 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03061-22: Section location: Body; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3N-03061-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
